Somatic mutation profile of tumor specimen 0630ecb0-b664-4e75-bb3c-fb62ee (aliquot 0630ecb0-b664-4e75-bb3c-fb62ee_D6_1) from CPTAC case 11CO052, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 0630ecb0-b664-4e75-bb3c-fb62ee: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69c23117-2b1e-475f-b1ea-0fc65bd1855d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 965f3b09-d548-48b9-8954-2fa73f (Blood Derived Normal), aliquot 965f3b09-d548-48b9-8954-2fa73f_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b866c68-d908-439d-88de-c39c8a5c799e

The open-access MAF lists 166 somatic variants for this specimen: 121 protein-altering or splice-affecting, 28 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 28, Nonsense Mutation 8, Intron 6, RNA 4, 5'Flank 3, Frame Shift Ins 3, Frame Shift Del 2, 3'UTR 2, 3'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COQ8A | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 55/424 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs119468009, CM081194; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 136/366 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 18/120 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 25/172 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2438C>T p.S813L | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795105, COSV60807773; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as COSV55596488; called by muse, mutect2, varscan2
- ACSS3 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs753775096, COSV54098217; called by muse, mutect2, varscan2
- ACTL9 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV61005539; called by muse, mutect2, varscan2
- ADAMTS9 | c.4543C>T p.R1515* | Nonsense Mutation (SNP) | VAF 13/118 reads (11%) | catalogued as COSV99899174; called by muse, mutect2, varscan2
- ADGRF1 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs150153137; called by muse, mutect2, varscan2
- AKAP13 | c.7663G>A p.E2555K (on ENST00000394518 / NM_007200.5; = p.E2559K on NM_006738.6) | Missense Mutation (SNP) | VAF 66/393 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs181607215; called by muse, mutect2, varscan2
- ALAS2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 145/494 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs863223900, COSV58188927; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKLE2 | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs746368812; called by muse, mutect2, varscan2
- APC | c.4128T>G p.Y1376* | Nonsense Mutation (SNP) | VAF 135/348 reads (39%) | catalogued as CD058149, CM106639, COSV57326134, COSV57340615, COSV57378080; called by muse, mutect2, varscan2
- ASIC4 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs975816858, COSV61730967; called by muse, mutect2, varscan2
- ATP5F1C | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.399); catalogued as rs758013111, COSV59621773; called by muse, mutect2, varscan2
- BCL9 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782465178, COSV52349605; called by muse, mutect2, varscan2
- CLEC14A | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as rs1412161057, COSV100643649; called by muse, mutect2, varscan2
- COL5A1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 88/648 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs745981084; called by muse, mutect2, varscan2
- DCC | c.3163+1G>A p.X1055_splice | Splice Site (SNP) | VAF 25/170 reads (15%) | catalogued as COSV59132031; called by muse, mutect2, varscan2
- DGKZ | c.946C>T p.R316* (on ENST00000454345 / NM_001105540.2; = p.R128* on NM_003646.4) | Nonsense Mutation (SNP) | VAF 16/434 reads (4%) | catalogued as COSV58984127, COSV58989965; called by muse, mutect2
- DHX15 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs924120935, COSV61026217; called by muse, mutect2, varscan2
- DMKN | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs1339343197; called by muse, mutect2, varscan2
- DSCAM | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs755881168, COSV68024346; called by muse, mutect2
- DSP | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1426930663, COSV65791559, COSV65795914; ClinVar: uncertain significance; called by muse, mutect2
- DYNC1H1 | c.13360G>A p.E4454K | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as rs1064797194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT4 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 87/584 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); catalogued as rs751131695, COSV67898608; called by muse, mutect2, varscan2
- FCN1 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 58/522 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV65662871; called by muse, mutect2, varscan2
- FGFR4 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 18/121 reads (15%) | catalogued as rs767126447, COSV104392508, COSV52801436; called by muse, mutect2, varscan2
- FKBP10 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs782511568, COSV58637928; called by muse, mutect2, varscan2
- FRAS1 | c.4363G>A p.A1455T | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.743); catalogued as rs771270397; called by muse, mutect2, varscan2
- FRMPD4 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV66222346; called by muse, mutect2, varscan2
- GALR2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs760968262; called by muse, mutect2
- GJA8 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 74/477 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782805555, COSV53789424; called by muse, mutect2, varscan2
- GRIA2 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV52404179; called by muse, mutect2, varscan2
- GRXCR2 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760103355, COSV100939976; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1642C>G p.R548G | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV56089393; called by muse, mutect2, varscan2
- HMCN1 | c.10050G>T p.E3350D | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV54898646; called by muse, mutect2, varscan2
- ITGA4 | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52001850, COSV52003303; called by muse, mutect2, varscan2
- KCNA3 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV63902637; called by muse, mutect2, varscan2
- KLHL40 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1254389648, COSV55138033; called by muse, mutect2, varscan2
- LAMC3 | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.349); catalogued as rs777019483; called by muse, mutect2, varscan2
- LRAT | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 71/569 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as COSV60476672; called by muse, mutect2, varscan2
- MAGEC3 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV53575632, COSV53580495; called by muse, mutect2
- MAGI2 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs369496058; called by muse, mutect2, varscan2
- MRGPRF | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as rs1227879038, COSV57995725; called by muse, mutect2, varscan2
- NTRK3 | c.601C>A p.R201S | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58124028; called by muse, mutect2, varscan2
- OCA2 | c.2190G>A p.W730* | Nonsense Mutation (SNP) | VAF 88/685 reads (13%) | catalogued as rs906306917, COSV62337818; called by muse, mutect2, varscan2
- OR10A7 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs373548663; called by muse, mutect2, varscan2
- OR52H1 | c.794G>A p.R265H (on ENST00000322653; = p.R271H on NM_001005289.1) | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs143065051; called by muse, mutect2, varscan2
- OTOG | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1338070656; called by muse, mutect2, varscan2
- PCDHA5 | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 89/679 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.08); catalogued as rs782079862; called by muse, mutect2, varscan2
- PGBD4 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.687); catalogued as rs1346676803; called by muse, mutect2, varscan2
- PLIN4 | c.3760G>A p.G1254R (on ENST00000301286; = p.G1269R on NM_001367868.2) | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs573666151, COSV56682553; called by muse, mutect2, varscan2
- PTGFR | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV66115553, COSV66115721; called by muse, mutect2, varscan2
- RAB6C | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV101308509; called by muse, mutect2, varscan2
- RIMS2 | c.1411C>T p.R471W (on ENST00000666250 / NM_001348490.2; = p.R279W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566248680, COSV51698013; called by muse, mutect2, varscan2
- RP1 | c.6398T>A p.L2133H | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV55114701, COSV99608701; called by muse, mutect2
- RPL15 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs376990079; called by muse, mutect2, varscan2
- SCGB3A1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs985524114, COSV99485006; called by muse, mutect2
- SEMA5B | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs1194747179, COSV99533357; called by muse, mutect2, varscan2
- SI | c.5168C>G p.S1723C | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100017193; called by muse, mutect2, varscan2
- SLC25A39 | c.557G>A p.R186Q (on ENST00000377095 / NM_001143780.3; = p.R178Q on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1048344765, COSV99835301; called by muse, mutect2, varscan2
- SMG7 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs914130337, COSV61631584; called by muse, mutect2, varscan2
- SRRM1 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1254361791; called by muse, mutect2, varscan2
- STON2 | c.854G>A p.R285H (on ENST00000649389 / NM_001366849.2; = p.R228H on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as rs1209190767; called by muse, mutect2, varscan2
- TENM4 | c.7279C>T p.R2427C | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774057206, COSV53672429; called by muse, mutect2, varscan2
- THSD7B | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs375482277; called by muse, mutect2, varscan2
- TSHZ1 | c.2399G>A p.R800H (on ENST00000580243 / NM_001308210.2; = p.R755H on NM_005786.6) | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs146830433; called by muse, mutect2, varscan2
- TSHZ3 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs766398534; called by muse, mutect2
- TSSK1B | c.1075dup p.Q359Pfs*18 | Frame Shift Ins (INS) | VAF 28/192 reads (15%) | catalogued as rs747842861; called by mutect2, varscan2
- USP5 | c.2152G>A p.A718T (on ENST00000229268 / NM_001098536.2; = p.A695T on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs202087351, COSV57538397; called by muse, mutect2, varscan2
- VN1R2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs199981144, COSV59037590, COSV59040122; called by muse, mutect2, varscan2
- WNT11 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 52/437 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs990623129, COSV59443668; called by muse, mutect2, varscan2
- ZNF385D | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs571099747, COSV55752958; called by muse, mutect2, varscan2
- ZNF536 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV62826633; called by muse, mutect2, varscan2
- ZNF578 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 89/336 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.185); catalogued as rs559140423, COSV69737221; called by muse, mutect2, varscan2
- ZNF99 | c.1952G>A p.C651Y | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68054825; called by muse, mutect2, varscan2
- ACSM4 | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADGRE2 | c.2149C>T p.L717F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPT2 | c.1170C>A p.F390L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BFSP1 | c.1910A>T p.Q637L | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- CALN1 | c.552C>A p.N184K (on ENST00000329008 / NM_001017440.3; = p.N226K on NM_031468.4) | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CCNC | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDKN1B | c.417_421dup p.Q141Pfs*6 | Frame Shift Ins (INS) | VAF 19/174 reads (11%) | called by mutect2, pindel, varscan2
- CNTN6 | c.899G>C p.S300T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- COL11A2 | c.2557G>T p.G853C (on ENST00000341947 / NM_080680.3; = p.G746C on NM_080679.2) | Missense Mutation (SNP) | VAF 165/574 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREBBP | c.2537_2540del p.P846Qfs*2 | Frame Shift Del (DEL) | VAF 34/247 reads (14%) | called by mutect2, pindel, varscan2
- CYP4A22 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2
- DMD | c.5882G>C p.S1961T | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.58); called by muse, mutect2
- DPP8 | c.1788T>G p.C596W (on ENST00000341861 / NM_001320875.2; = p.C580W on NM_017743.6) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2
- FAM169A | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.116); called by muse, mutect2
- FRYL | c.8269C>T p.P2757S | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBP5 | c.327C>G p.N109K | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GNG11 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR137B | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HLA-G | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- IER5L | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- IFT88 | c.2200C>A p.Q734K (on ENST00000319980 / NM_001318493.2; = p.Q725K on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- INSYN2B | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- INTS1 | c.5498G>A p.C1833Y | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIR2DL4 | c.1030C>T p.H344Y (on ENST00000396284; = p.H270Y on NM_001080770.2) | Missense Mutation (SNP) | VAF 49/447 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- MEIS1 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MNT | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- MTMR6 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- MTUS1 | c.3001dup p.T1001Nfs*8 (on ENST00000262102 / NM_001363061.1; = p.T167Nfs*8 on NM_020749.4) | Frame Shift Ins (INS) | VAF 56/350 reads (16%) | called by mutect2, pindel, varscan2
- OAS2 | c.1583A>C p.Q528P | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OBSCN | c.4250C>G p.T1417S | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ORC6 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLBD2 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 67/473 reads (14%) | called by muse, mutect2, varscan2
- PRR23B | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 58/297 reads (20%) | called by muse, mutect2, varscan2
- RANBP6 | c.3157G>T p.G1053* | Nonsense Mutation (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 90/486 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFPL4AL1 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 48/553 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2
- RNPEPL1 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1 | c.3622C>A p.L1208I | Missense Mutation (SNP) | VAF 64/500 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- RP1 | c.6400T>A p.F2134I | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.166); called by muse, mutect2
- RRAGA | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 59/383 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TLR6 | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZFP36L2 | c.265_272del p.S89Gfs*11 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel
- ZNF483 | c.1825T>C p.C609R | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM5 | c.1938G>A p.T646= | Silent (SNP) | VAF 111/353 reads (31%) | catalogued as rs144920263; called by muse, mutect2, varscan2
- CSMD2 | c.3918C>T p.A1306= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs759186632; called by muse, mutect2, varscan2
- EPHA5 | c.1257C>T p.S419= | Silent (SNP) | VAF 39/321 reads (12%) | catalogued as rs753971619, COSV56631266, COSV56675035, COSV56676610; called by muse, mutect2, varscan2
- GRID1 | c.1962C>A p.A654= | Silent (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- IFI6 | c.351C>T p.Y117= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs374664445; called by muse, mutect2, varscan2
- IFIT2 | c.579C>T p.N193= | Silent (SNP) | VAF 38/269 reads (14%) | catalogued as rs371496568; called by muse, mutect2, varscan2
- IGHV1-46 | c.169C>A p.R57= | Silent (SNP) | VAF 82/623 reads (13%) | called by mutect2, varscan2
- KCNC1 | c.1131C>T p.S377= | Silent (SNP) | VAF 15/448 reads (3%) | catalogued as rs1481676892, COSV99788810; called by muse, mutect2
- KCNT1 | c.2079C>T p.P693= (on ENST00000488444; = p.P712= on NM_020822.3) | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs377516058; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF26B | c.5595C>T p.S1865= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1457400224, COSV63645192; called by muse, mutect2, varscan2
- LRRC38 | c.696G>A p.S232= | Silent (SNP) | VAF 38/310 reads (12%) | catalogued as rs892402776, COSV65790823; called by muse, mutect2, varscan2
- MIA2 | c.690A>G p.G230= | Silent (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- MMP28 | c.1527C>T p.G509= | Silent (SNP) | VAF 32/209 reads (15%) | called by muse, mutect2, varscan2
- MTA1 | c.219G>A p.P73= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs140261141; called by muse, mutect2, varscan2
- NCAPD3 | c.2880C>T p.N960= | Silent (SNP) | VAF 26/198 reads (13%) | catalogued as rs779883403; called by muse, mutect2, varscan2
- NEUROD1 | c.141C>T p.N47= | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as rs1046216784, COSV54549546; called by muse, mutect2
- NRG1 | c.273G>A p.K91= (on ENST00000523534; = p.K238= on NM_013962.2) | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- PAPPA2 | c.2316C>T p.A772= | Silent (SNP) | VAF 31/234 reads (13%) | catalogued as rs746153479; called by muse, mutect2, varscan2
- PCDHA12 | c.2202G>A p.P734= | Silent (SNP) | VAF 61/281 reads (22%) | catalogued as COSV56488495, COSV99166277; called by muse, mutect2, varscan2
- PCDHB4 | c.336G>A p.P112= | Silent (SNP) | VAF 16/368 reads (4%) | catalogued as rs782599988; called by muse, mutect2
- PNLIP | c.405G>A p.S135= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs147151438; called by muse, mutect2, varscan2
- PRSS35 | c.1236C>T p.Y412= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs1484935431; called by muse, mutect2, varscan2
- PTCHD3 | c.1218C>T p.D406= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs934503118, COSV101438975; called by muse, mutect2, varscan2
- SCN5A | c.1914C>T p.G638= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs764488677, COSV61128636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLL1 | c.1632C>T p.D544= | Silent (SNP) | VAF 39/216 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.2256T>C p.R752= (on ENST00000591111; = p.R706= on NM_003319.4) | Silent (SNP) | VAF 20/585 reads (3%) | called by muse, mutect2
- TXK | c.588G>T p.T196= | Silent (SNP) | VAF 21/146 reads (14%) | catalogued as rs751767258, COSV51918092, COSV99972528; called by muse, mutect2, varscan2
- ZSCAN1 | c.588C>T p.R196= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs563031274, COSV56604944; called by muse, mutect2, varscan2
- AC068631.2 | chr3:186597186 G>A | 3'Flank (SNP) | VAF 33/204 reads (16%) | called by muse, mutect2, varscan2
- AC134312.1 | n.949G>A | RNA (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- BBS9 | c.1329+1652T>A | Intron (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- C11orf40 | n.164T>C | RNA (SNP) | VAF 15/155 reads (10%) | catalogued as rs1252521223; called by muse, mutect2, varscan2
- DNM1P47 | n.576C>A | RNA (SNP) | VAF 65/517 reads (13%) | catalogued as rs1383335030; called by muse, mutect2, varscan2
- DST-AS1 | n.139+7459G>C | Intron (SNP) | VAF 43/309 reads (14%) | called by muse, mutect2, varscan2
- GALNS | c.121-235C>T | Intron (SNP) | VAF 25/191 reads (13%) | catalogued as rs775572197; called by muse, mutect2, varscan2
- HOXA10 | c.*188T>C | 3'UTR (SNP) | VAF 61/555 reads (11%) | called by muse, mutect2, varscan2
- ITGA9 | c.2434-12C>G | Intron (SNP) | VAF 33/239 reads (14%) | called by muse, mutect2, varscan2
- LGR6 | chr1:202189294 C>T | 5'Flank (SNP) | VAF 32/166 reads (19%) | catalogued as rs748336834; called by muse, mutect2, varscan2
- LMF1 | c.504-36A>G | Intron (SNP) | VAF 43/267 reads (16%) | catalogued as rs757668601; called by muse, mutect2, varscan2
- NT5DC3 | chr12:103844158 C>A | 5'Flank (SNP) | VAF 32/136 reads (24%) | catalogued as rs1178748688; called by muse, mutect2
- PCDHGA10 | c.2436+85_2436+86dup | Intron (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- PNISR | c.*40T>A | 3'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as rs1002280344; called by muse, mutect2
- POU6F2 | c.-1A>C | 5'UTR (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- ZNF22 | chr10:45000670 A>G | 5'Flank (SNP) | VAF 27/140 reads (19%) | catalogued as rs745717369; called by muse, mutect2, varscan2
- ZNF890P | n.771G>A | RNA (SNP) | VAF 7/73 reads (10%) | catalogued as rs770674202; called by muse, mutect2, varscan2
